CCDI case PBCNLW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f3c4a0c8-a7c7-47db-ab70-63b191d7562d

Demographics
Sex at birth: male.

Diagnoses (1)
1. Meningothelial meningioma: ICD-O-3 morphology code: 9531/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.2 years (3,346 days).

Biospecimens (3 samples)
- Sample 0DW72O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW72V: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW72Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
